Somatic mutation profile of tumor specimen TCGA-MJ-A850-01A (aliquot TCGA-MJ-A850-01A-11D-A351-09) from TCGA case TCGA-MJ-A850, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 28.6 years (10,451 days).
Specimen TCGA-MJ-A850-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e65c7c5e-c970-44b0-9651-3cdd78458356.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MJ-A850-10A (Blood Derived Normal), aliquot TCGA-MJ-A850-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5a54785-866b-4e29-b997-92e73d70a4b7

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs764563080, COSV100382512, COSV60631257; called by muse, mutect2, varscan2
- ARHGEF37 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV100381843; called by muse, mutect2, varscan2
- DGKA | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100092523; called by muse, mutect2
- EIF4A3 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV53921612, COSV99484165; called by muse, mutect2, varscan2
- GRIN3A | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759241167, COSV100701321; called by muse, mutect2, varscan2
- MUC16 | c.21092C>A p.P7031H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.263); catalogued as COSV67464459; called by muse, mutect2
- OR5M10 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101595856, COSV73242351; called by muse, mutect2, varscan2
- RFPL3 | c.443G>A p.R148Q (on ENST00000249007 / NM_001098535.1; = p.R119Q on NM_006604.2) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as rs746530586, COSV50750179; called by muse, mutect2, varscan2
- RNF213 | c.11693C>T p.S3898F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100299419; called by muse, mutect2, varscan2
- SLC22A8 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs45566039, COSV100267647; called by muse, mutect2, varscan2
- SMOC2 | c.781G>A p.V261I (on ENST00000356284 / NM_001166412.2; = p.V272I on NM_022138.3) | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554225332, COSV100634634; called by muse, mutect2, varscan2
- TRPV6 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs765418597, COSV100844061, COSV63892873; called by muse, mutect2, varscan2
- TTN | c.15028G>A p.D5010N (on ENST00000591111; = p.D4083N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | PolyPhen probably damaging (0.998); catalogued as rs868056944, COSV100612811, COSV59863267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC93B1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750571331, COSV57097564; called by muse, mutect2
- WFIKKN1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1483364756, COSV99937478; called by muse, mutect2, varscan2
- CCDC141 | c.2792dup p.N931Kfs*2 | Frame Shift Ins (INS) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- CDKL1 | c.999C>T p.S333= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV99367143; called by muse, mutect2, varscan2
- DSG2 | c.1062C>T p.V354= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs369233023; ClinVar: likely benign; called by muse, mutect2
- NEU4 | c.90G>T p.V30= (on ENST00000391969 / NM_001167602.3; = p.V42= on NM_080741.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1010481682, COSV100371771; called by muse, mutect2, varscan2
- TENM2 | c.2871C>T p.Y957= (on ENST00000518659 / NM_001122679.2; = p.Y725= on NM_001080428.3) | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs375197936; called by muse, mutect2, varscan2
